Somatic mutation profile of tumor specimen TCGA-06-0119-01A (aliquot TCGA-06-0119-01A-08D-1490-08) from TCGA case TCGA-06-0119, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.1 years (29,606 days).
Specimen TCGA-06-0119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dff16bc-b2cf-4b74-83b2-d89c442c28c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0119-10A (Blood Derived Normal), aliquot TCGA-06-0119-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/712ed64e-c763-4741-8fdc-a0b0f5c542fe

The open-access MAF lists 70 somatic variants for this specimen: 59 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 10, Nonsense Mutation 6, Splice Site 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199474785, CM002379, COSV62197747; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC127029.3 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as rs781542704, COSV60111792; called by muse, mutect2
- ADAM30 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65561903; called by muse, mutect2, varscan2
- ADAMTS16 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as rs773867274, COSV57003634; called by muse, mutect2, varscan2
- ARL13A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766355429, COSV65880327; called by muse, mutect2, varscan2
- ARSL | c.455G>C p.C152S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1204479275, COSV66965700; called by muse, mutect2, varscan2
- C2orf16 | c.1934T>C p.V645A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV62677706; called by muse, mutect2, varscan2
- CACNA1D | c.2629G>A p.V877I (on ENST00000350061 / NM_001128840.3; = p.V897I on NM_000720.4) | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs564937293, COSV55461098; called by muse, mutect2, varscan2
- CEACAM21 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs782587120, COSV51816030; called by muse, mutect2
- COG2 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV64188028; called by muse, mutect2, varscan2
- COL12A1 | c.6067+1G>A p.X2023_splice | Splice Site (SNP) | VAF 6/73 reads (8%) | catalogued as COSV59405148; called by muse, mutect2
- COL1A2 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070816, COSV51964226; called by muse, mutect2
- COL6A3 | c.2959G>A p.V987M | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs140437593; ClinVar: uncertain significance; called by muse, varscan2
- CSN2 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.242); catalogued as rs375072668, COSV61992564; called by muse, mutect2
- DDX11 | c.2272-1G>T p.X758_splice (on ENST00000545668 / NM_152438.2; = p.X708_splice on NM_004399.3) | Splice Site (SNP) | VAF 19/171 reads (11%) | catalogued as COSV52509376; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- GPR52 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1453719313, COSV52296355; called by muse, mutect2
- HMCN1 | c.9053G>A p.R3018Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs780839537, COSV54931982; called by muse, varscan2
- HNRNPH2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); catalogued as rs1555988491, COSV54510353; called by muse, mutect2
- IRAK1 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57656232; called by muse, mutect2, varscan2
- JADE3 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs781975611, COSV54469378; called by muse, mutect2, varscan2
- KCTD16 | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72580294; called by muse, mutect2, varscan2
- KIAA1109 | c.8648G>T p.G2883V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52670331, COSV52688179; called by muse, mutect2, varscan2
- KLK6 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs553226234, COSV100037844, COSV59564993; called by muse, mutect2, varscan2
- LHX3 | c.152G>T p.W51L (on ENST00000371748 / NM_178138.6; = p.W56L on NM_014564.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65583058; called by mutect2, varscan2
- LRP2 | c.13754G>A p.R4585Q | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs764511347, COSV55540466; called by muse, mutect2
- MAGEB1 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66776432; called by muse, mutect2, varscan2
- MTMR4 | c.1656G>T p.M552I | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60202754; called by muse, mutect2, varscan2
- MTMR4 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60202761; called by muse, mutect2, varscan2
- MXRA5 | c.6356G>A p.R2119H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as rs749329546, COSV54230521; called by muse, mutect2, varscan2
- NAT10 | c.92A>C p.D31A | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57665796; called by muse, mutect2
- NUP107 | c.1766T>C p.I589T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs752781760, COSV57497415; called by muse, mutect2
- OR12D2 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV65829787; called by muse, mutect2, varscan2
- OR2A12 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV68821865; called by muse, mutect2, varscan2
- OR56A4 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs116778909, COSV58109297; called by muse, mutect2, varscan2
- OR8K3 | c.324T>G p.I108M | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.291); catalogued as COSV57132544; called by muse, mutect2
- PLEC | c.13642G>A p.A4548T (on ENST00000322810 / NM_201380.4; = p.A4438T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV59681952; called by muse, mutect2
- PTGIS | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 16/214 reads (7%) | catalogued as rs370453415; called by muse, mutect2
- PTK2B | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV57763941; called by muse, mutect2
- RAD54B | c.1753A>T p.I585L | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV60254077; called by muse, mutect2, varscan2
- RBM10 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.432); catalogued as rs782440714, COSV61311461; called by muse, mutect2, varscan2
- REXO1 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50087693; called by muse, mutect2
- RHOXF1 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV54295575; called by muse, mutect2, varscan2
- RMI1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV57937537; called by muse, mutect2, varscan2
- SEMA3E | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs1420638220, COSV57090545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD3 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs767134713, COSV59286611; called by muse, mutect2, varscan2
- SLC26A11 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV58340212; called by muse, mutect2, varscan2
- SLC35C2 | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54758172; called by muse, mutect2
- SLC6A14 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781806347, COSV64148333; called by muse, mutect2, varscan2
- SLC9A4 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs199784614, COSV54837994; called by mutect2, varscan2
- SLCO1A2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148616059; called by muse, mutect2, varscan2
- SPAG17 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV60466065; called by muse, mutect2, varscan2
- TRHDE | c.2396T>A p.F799Y | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV53861162; called by muse, mutect2, varscan2
- YLPM1 | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs940867899, COSV53118735; called by muse, mutect2, varscan2
- ZC2HC1A | c.210+1G>A p.X70_splice | Splice Site (SNP) | VAF 22/162 reads (14%) | catalogued as COSV55670981; called by muse, mutect2, varscan2
- ZSCAN22 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV61639518; called by muse, mutect2
- ADGRG6 | c.2673del p.K891Nfs*11 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel
- SPANXB1 | c.139A>T p.K47* | Nonsense Mutation (SNP) | VAF 48/1554 reads (3%) | called by muse, mutect2
- TEKT2 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); called by muse, mutect2
- ANO8 | c.2829C>T p.S943= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs144454643; called by muse, mutect2, varscan2
- FADS6 | c.507G>A p.T169= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs767030840, COSV59603513; called by muse, mutect2, varscan2
- FAM47A | c.1518G>A p.S506= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs752647537, COSV60495640; called by muse, varscan2
- GAS2L2 | c.1335C>T p.A445= | Silent (SNP) | VAF 27/245 reads (11%) | called by muse, mutect2
- NUFIP2 | c.1014A>G p.K338= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV56605504, COSV99837352; called by muse, mutect2, varscan2
- PCDHB15 | c.2112G>A p.S704= | Silent (SNP) | VAF 42/370 reads (11%) | catalogued as rs1414282932, COSV50921645; called by muse, varscan2
- PHOX2B | c.492G>A p.A164= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs761776635, COSV56930104, COSV99891323; called by muse, mutect2
- PKDREJ | c.2214C>T p.I738= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as rs368849728; called by muse, mutect2, varscan2
- THEMIS | c.897C>T p.S299= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV64073685; called by muse, mutect2, varscan2
- TTC22 | c.291G>A p.P97= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1288431922, COSV100988130, COSV64881898; called by muse, mutect2, varscan2
- MARCHF1 | c.163-10G>C | Intron (SNP) | VAF 17/146 reads (12%) | catalogued as COSV99921261; called by muse, mutect2, varscan2
